Somatic mutation profile of tumor specimen TCGA-IB-A5SQ-01A (aliquot TCGA-IB-A5SQ-01A-11D-A32N-08) from TCGA case TCGA-IB-A5SQ, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 56.8 years (20,760 days).
Specimen TCGA-IB-A5SQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6c710e5-e4f9-42e7-95fe-03e56acdb265.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-A5SQ-10A (Blood Derived Normal), aliquot TCGA-IB-A5SQ-10A-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12b1c94b-b144-46f4-9217-3a888157628c

The open-access MAF lists 35 somatic variants for this specimen: 26 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 25, Silent 9, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.3575G>A p.R1192H | Missense Mutation (SNP) | VAF 19/433 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60785906, COSV60794673; called by muse, mutect2
- ARHGAP10 | c.1831G>A p.V611M | Missense Mutation (SNP) | VAF 34/486 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.475); catalogued as rs756362452, COSV100331913; called by muse, mutect2
- ARHGAP17 | c.2297T>C p.L766P (on ENST00000289968 / NM_001006634.3; = p.L688P on NM_018054.6) | Missense Mutation (SNP) | VAF 80/892 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as rs1232097032, COSV99254210; called by muse, mutect2
- CRACD | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV99950208; called by muse, mutect2
- DACH2 | c.1104G>T p.K368N | Missense Mutation (SNP) | VAF 34/434 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV100914115; called by muse, mutect2
- DNAH11 | c.10750C>G p.H3584D | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as COSV100181437; called by muse, mutect2
- DOCK10 | c.4979G>A p.R1660H | Missense Mutation (SNP) | VAF 52/712 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs1305763186, COSV51420167; called by muse, mutect2
- EPHA1 | c.785G>A p.C262Y | Missense Mutation (SNP) | VAF 38/506 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV99314950; called by muse, mutect2
- FAM135B | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV99428661; called by muse, mutect2
- FAM181A | c.223T>G p.F75V | Missense Mutation (SNP) | VAF 18/386 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99968024; called by muse, mutect2
- GLB1L | c.700A>C p.T234P | Missense Mutation (SNP) | VAF 69/1053 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV99850989; called by muse, mutect2
- KLK11 | c.361G>A p.A121T (on ENST00000594768 / NM_144947.3; = p.A89T on NM_006853.3) | Missense Mutation (SNP) | VAF 27/616 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV51579318; called by muse, mutect2
- MACF1 | c.12860C>T p.S4287F (on ENST00000372915; = p.S2220F on NM_012090.5) | Missense Mutation (SNP) | VAF 29/416 reads (7%) | catalogued as COSV99247540; called by muse, mutect2
- OR10C1 | c.233C>T p.T78M (on ENST00000622521; = p.T76M on NM_013941.3) | Missense Mutation (SNP) | VAF 42/608 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.37); catalogued as COSV101010795; called by muse, mutect2
- OR5F1 | c.223A>C p.T75P | Missense Mutation (SNP) | VAF 35/335 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV99559004; called by muse, mutect2, varscan2
- PLEC | c.7930C>T p.R2644C (on ENST00000322810 / NM_201380.4; = p.R2534C on NM_000445.5) | Missense Mutation (SNP) | VAF 23/222 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.226); catalogued as rs782503698, COSV100519994; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RDX | c.1141C>T p.R381* | Nonsense Mutation (SNP) | VAF 36/502 reads (7%) | catalogued as rs1308348441, COSV100563157; called by muse, mutect2
- SHD | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 28/402 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs200550741, COSV101619075; called by muse, mutect2
- SLCO1B3 | c.537G>A p.M179I | Missense Mutation (SNP) | VAF 35/590 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as rs777788484, COSV99682442; called by muse, mutect2
- SOGA3 | c.2528C>T p.A843V | Missense Mutation (SNP) | VAF 42/936 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.27); catalogued as rs1158069206, COSV64104892; called by muse, mutect2
- SPRED1 | c.843G>C p.Q281H | Missense Mutation (SNP) | VAF 40/388 reads (10%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV100136506; called by muse, mutect2
- TAS2R50 | c.579A>G p.I193M | Missense Mutation (SNP) | VAF 32/500 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.385); catalogued as COSV101115931; called by muse, mutect2
- TET3 | c.3019G>A p.A1007T | Missense Mutation (SNP) | VAF 58/732 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs754843346, COSV69643269, COSV69645136; called by muse, mutect2
- WNT3A | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 29/328 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs908046368, COSV52732415; called by muse, mutect2
- YTHDF1 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 39/604 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100945645; called by muse, mutect2
- FCGBP | c.6856G>A p.A2286T | Missense Mutation (SNP) | VAF 31/632 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.066); called by muse, mutect2
- CAPN11 | c.1065C>T p.D355= | Silent (SNP) | VAF 32/422 reads (8%) | catalogued as rs370482641; called by muse, mutect2
- DCAF4L2 | c.1137A>G p.P379= | Silent (SNP) | VAF 59/425 reads (14%) | catalogued as COSV100151409; called by muse, mutect2, varscan2
- GPR162 | c.780G>A p.S260= | Silent (SNP) | VAF 26/401 reads (6%) | catalogued as rs782022580, COSV99163978; called by muse, mutect2
- NSD1 | c.705A>G p.T235= | Silent (SNP) | VAF 25/317 reads (8%) | catalogued as COSV100729934; called by muse, mutect2
- NUP210 | c.3735C>T p.G1245= | Silent (SNP) | VAF 35/360 reads (10%) | catalogued as COSV99597251; called by muse, mutect2
- PKN1 | c.2622C>T p.F874= | Silent (SNP) | VAF 30/406 reads (7%) | catalogued as COSV99466715; called by muse, mutect2
- QDPR | c.678C>T p.S226= | Silent (SNP) | VAF 34/495 reads (7%) | catalogued as COSV99845998; called by muse, mutect2
- SAMSN1 | c.435T>C p.G145= | Silent (SNP) | VAF 32/396 reads (8%) | catalogued as COSV99582673; called by muse, mutect2
- SYTL2 | c.73C>T p.L25= | Silent (SNP) | VAF 142/1742 reads (8%) | catalogued as COSV60357987; called by muse, mutect2
